Gene-level copy-number profile of tumor specimen TARGET-10-PARNXJ-09A from TARGET case TARGET-10-PARNXJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.8 years (1,760 days).
Specimen TARGET-10-PARNXJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.834518a0-8809-55d3-8a80-9df50ecaf87d.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARNXJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 358 have no estimate.
https://portal.gdc.cancer.gov/files/8477a7b7-db9e-4e5f-8263-ce195ba76556

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,524; copy number 1: 122; copy number 2: 56,771; copy number 3: 619; copy number 4: 34; copy number 5: 191; copy number 6: 4.

Homozygous deletions (total copy number 0; autosomes only): 146 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:152,600,662–152,614,098, 2 genes: LCE3C, LCE3B.
- chr4:108,047,545–108,168,956, 1 gene (within-gene range 0–2): LEF1.
- chr6:285,443–351,355, 2 genes: AL365272.1, DUSP22.
- chr7:38,291,616–38,318,861, 5 genes: TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:142,529,290–142,813,399, 50 genes: TRBV7-9, TRBV13, TRBV10-3, TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2, TRBV30.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–21,995,301, 5 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,012,536, 3 genes: AL449423.1, CDKN2B, UBA52P6.
- chr10:87,863,625–88,049,823, 5 genes (within-gene range 0–2): PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr14:21,887,857–22,490,553, 69 genes (broad region; genes not listed).
- chr16:55,760,566–55,793,960, 1 gene (within-gene range 0–2): CES1P1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 195 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:74,918,148–74,970,128, 4 genes, copy number 6: LINC01291, AC104135.1, LINC01293, POLE4.
- chr8:7,170,550–8,059,674, 75 genes, copy number 5 (broad region; genes not listed).
- chr8:8,065,599–8,065,816, 1 gene, copy number 5: AC105233.5.
- chr14:105,785,505–106,443,583, 115 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 112. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
